Gene-level copy-number profile of tumor specimen TCGA-D3-A3C3-06A from TCGA case TCGA-D3-A3C3, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS.
Specimen TCGA-D3-A3C3-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.b657c3f2-700a-414e-ab5b-561a9844dedb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D3-A3C3-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fc937915-d1d1-4c85-b671-2c524cdbaaad

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 39; copy number 1: 525; copy number 2: 8,555; copy number 3: 37,126; copy number 4: 9,374; copy number 5: 3,457; copy number 6: 243; copy number 7: 70; copy number 9: 140; copy number 10: 67; copy number 11: 125; copy number 13: 22; copy number 15: 9; copy number 17: 63.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D3-A3C3-06A-12D-A192-01): tumor purity 0.57, ploidy 3.1, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 39 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:102,256,604–103,065,598, 8 genes: RNU6-329P, AL442644.2, AL442644.1, LINC00587, ZYG11AP1, AL365396.1, CYLC2, AL589823.1.
- chr9:122,675,036–123,930,152, 31 genes (within-gene range 0–2): OR1L3, TLK1P1, OR1L4, OR1L6, SKA2P1, OR5C1, PDCL, OR1K1, KRT18P67, RC3H2, SNORD90, ZBTB6, ZBTB26, AC007066.2, AC007066.3, RABGAP1, RNY1P15, AC007066.1, GPR21, AL365338.1, MIR600HG, STRBP, MIR600, CRB2, DENND1A, MIR601, MIR7150, AL445489.1, AL390774.2, AL390774.1, PIGFP2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 496 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,257,879–38,311,808, 8 genes, copy number 10: TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1.
- chr7:126,438,598–127,253,093, 1 gene, copy number 9 (within-gene range 4–9): GRM8.
- chr7:126,868,767–129,757,082, 89 genes, copy number 9–11 (within-gene range 4–11) (broad region; genes not listed).
- chr7:130,380,339–132,087,992, 45 genes, copy number 11: CPA1, CEP41, AC007938.1, MESTIT1, MEST, AC007938.5, AC007938.6, AC007938.4, AC007938.2, MIR335, COPG2, AC007938.3, AUXG01000058.1, RNA5SP246, AC234644.1, TSGA13, AC234644.2, KLF14, AC016831.5, AC016831.6, AC016831.2, H4P1, AC016831.3, LINC00513, MIR29A, AC016831.1, MIR29B1, AC016831.4, AC058791.1, LINC-PINT, RNU6-1010P, MKLN1, AC009362.1, MKLN1-AS, AC008264.2, PODXL, AC008264.1, EEF1B2P6, AC093106.1, AC093106.2, NDUFB9P2, CAPZA1P4, AC009518.2, AC009518.1, AC105443.1.
- chr7:132,264,152–132,271,269, 1 gene, copy number 10: AC018643.1.
- chr7:133,082,829–133,170,514, 2 genes, copy number 10: RNU6-92P, ST13P7.
- chr7:133,290,881–133,315,413, 2 genes, copy number 10: MIR6133, AC083875.1.
- chr7:134,986,508–135,510,127, 13 genes, copy number 9: AGBL3, CYREN, RNF14P4, TMEM140, AC083862.1, AC083862.2, WDR91, AC009542.1, MIR6509, STRA8, SLC23A4P, CNOT4, SDHDP2.
- chr7:136,092,913–136,437,785, 1 gene, copy number 7 (within-gene range 5–7): AC078845.1.
- chr7:136,262,558–141,052,409, 89 genes, copy number 7–17 (broad region; genes not listed).
- chr7:142,941,114–144,008,793, 52 genes, copy number 9 (within-gene range 6–9): KEL, OR9A2, OR9P1P, OR6V1, OR6W1P, PIP, TAS2R39, AC073342.1, TAS2R40, AC073342.2, GSTK1, TMEM139-AS1, TMEM139, CASP2, RN7SL535P, RN7SL481P, HINT1P1, CLCN1, FAM131B, AC093673.2, AC093673.1, ZYX, MIR6892, EPHA1, EPHA1-AS1, TAS2R62P, TAS2R60, TAS2R41, OR2R1P, OR10AC1, AC073264.1, PAICSP5, CTAGE15, RNU6-162P, AC073264.2, TCAF1P1, AC073264.3, TCAF2, TCAF2C, RNU6-267P, CTAGE6, AC099548.2, PAICSP6, AC099548.1, TCAF2P1, TCAF1, OR2F2, OR2F1, CAPZA1P5, OR2Q1P, SLC16A1P1, OR6B1.
- chr7:144,123,176–144,836,395, 22 genes, copy number 13 (within-gene range 5–13): OR2A14, OR2A13P, OR2A3P, OR2AO1P, CTAGE4, ARHGEF35, ARHGEF35-AS1, OR2A42, OR2A20P, AC074386.1, OR2A7, CTAGE8, ARHGEF34P, OR2A9P, OR2A1-AS1, OR2A1, ARHGEF5, NOBOX, PPIAP83, RNU6ATAC40P, TPK1, EEF1A1P10.
- chr7:145,583,197–148,420,998, 15 genes, copy number 9 (within-gene range 6–9): DPY19L4P2, AC006007.1, AC073308.1, CNTNAP2, AC073418.1, Y_RNA, CNTNAP2-AS1, DUTP3, RANP2, MIR548F4, AC005518.1, AC005518.2, RNU6-1184P, RNA5SP249, RN7SL456P.
- chr7:150,944,961–152,447,150, 51 genes, copy number 10: KCNH2, NOS3, ATG9B, ABCB8, AC010973.1, ASIC3, CDK5, SLC4A2, AC010973.3, AC010973.2, FASTK, TMUB1, AGAP3, GBX1, ASB10, IQCA1L, H2BE1, ABCF2-H2BE1, ABCF2, CHPF2, MIR671, SMARCD3, AC021097.1, AC005486.1, NUB1, WDR86, WDR86-AS1, AC005996.1, CRYGN, MIR3907, RN7SL76P, RHEB, ETF1P2, PRKAG2, AC093583.1, PRKAG2-AS1, RNU6-604P, Y_RNA, AC074257.1, GALNTL5, Metazoa_SRP, GALNT11, AC006017.1, YBX1P4, KMT2C, AC104692.2, AC104692.1, SEPTIN7P6, Y_RNA, FABP5P3, CCT8L1P.
- chr7:154,544,169–154,547,285, 1 gene, copy number 10: AC024730.1.
- chr7:155,644,451–157,527,325, 30 genes, copy number 9 (within-gene range 5–9): RBM33, SHH, AC021218.1, Y_RNA, AC093813.1, LINC01006, LINC00244, AC005534.1, RNF32, RNF32-AS1, LMBR1, RNU4-31P, AC006357.1, NOM1, MNX1, MNX1-AS2, MNX1-AS1, AC006967.2, AC006967.1, AC006967.3, UBE3C, RPS27AP12, AC004898.1, AC004975.1, AC004975.2, DNAJB6, AC006372.3, AC006372.1, AC006372.2, AC006372.4.
- chr7:157,574,336–157,989,456, 6 genes, copy number 9: MIR153-2, AC005481.1, AC006003.1, PTPRN2-AS1, AC011899.2, AC011899.3.
- chr7:159,107,761–159,233,377, 2 genes, copy number 10: AC007269.1, PIP5K1P2.
- chr14:22,112,347–22,513,998, 66 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 525. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
